Surgical pathology report (de-identified scan), TCGA case TCGA-L9-A444, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Candler, specimen TCGA-L9-A444-01A (Primary Tumor).

[page 1 of 4]
RUN DATE: [REDACTED] PAGE 1
RUN TIME: [REDACTED] Specimen Inquiry
RUN USER: [REDACTED] Lab Database:

PATIENT: [REDACTED] ACCT #: [REDACTED] LOC: [REDACTED] U #: [REDACTED]
REG DR: [REDACTED] AGE/SX: [REDACTED] ROOM: [REDACTED] REG: [REDACTED]
DOB: [REDACTED] BED: [REDACTED] DIS: [REDACTED]
STATUS: [REDACTED] TLOC: [REDACTED]

SPEC #: [REDACTED] RECD: [REDACTED] STATUS: [REDACTED] PERFORMED AT [REDACTED]
COLL: [REDACTED] TIME IN FORMALIN: [REDACTED]

CLINICAL INFORMATION:

Pre-Op Diagnosis: Lung CA

Remarks:

Specimen(s): A. Level 7 (frozen section)
B. Level 4 (frozen)
C. R4
D. Right upper lobe
E. Level 10

MICROSCOPIC DIAGNOSIS

ICD-O-3

adenocarcinoma, NOS

8140/3

Site: lung, upper lobe

C34.1

8/23/12
RD

- A. LEVEL 7 LYMPH NODE:
- REACTIVE LYMPH NODE
- B. LEVEL 4 LYMPH NODE:
- REACTIVE LYMPH NODE
- C. R4 LYMPH NODE:
- REACTIVE LYMPH NODE
- D. RIGHT UPPER LOBE:
- ADENOCARCINOMA
- SEE COMMENT FOR DETAILS
- E. LEVEL 10 LYMPH NODE:
- REACTIVE LYMPH NODE

COMMENT(S)

PROTOCOL FOR EXAMINATION OF SPECIMENS WITH PRIMARY NON SMALL CELL CARCINOMA OF THE LUNG
BASED ON AJCC/UICC TNM 7TH EDITION

LUNG: Resection
SPECIMEN: Lobe
PROCEDURE: Lobectomy
SPECIMEN INTEGRITY: Intact
SPECIMEN LATERALITY: Right
TUMOR SITE: Upper lobe
TUMOR SIZE: 1.5 cm

** CONTINUED ON NEXT PAGE **

IFAA Discrepancy		X

8/19/12

[page 2 of 4]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

PAGE 2

Specimen Inquiry

PCI User: [REDACTED] Lab Database:

SPEC #: [REDACTED] PATIENT: [REDACTED] (Continued)

COMMENT (S)

(Continued)

TUMOR FOCALITY:	Unifocal
HISTOLOGIC TYPE:	Adenocarcinoma
HISTOLOGIC GRADE:	G2, moderately differentiated
VISCERAL PLEURAL INVASION:	Not identified
TUMOR EXTENSION:	Not applicable
MARGINS:	Bronchial Margin: Uninvolved by invasive carcinoma Vascular Margin: Uninvolved by invasive carcinoma Parenchymal Margin: Not applicable Parietal Pleural Margin: Not applicable Chest Wall Margin: Not applicable
TREATMENT EFFECT:	Not applicable
LYMPH-VASCULAR INVASION:	Not identified
PATHOLOGIC STAGING:	Primary Tumor: pT1a Regional Lymph Node: pN0 Number of lymph nodes examined: 6 Number of lymph nodes involved: 0 Distance Metastasis: Not applicable

GROSS DESCRIPTION:

A. Received in the unfixed state in the operating room labeled "level 7 lymph node". The specimen consists of multiple tan-red fragments of tissue aggregating to 1.5 x 0.5 x 0.3 cm. One smear imprint is prepared. All the specimen is frozen in one block.

B. Labeled "level 4 lymph node". The specimen is received in an unfixed state in the Operating Room, consistent with a single 0.5 cm reddish tan piece of tissue entirely frozen in one block.

C. Part 3 labeled "R4". Received in formalin, is a 0.5 x 0.4 x 0.3 cm mildly anthracotic to pink/tan lymph node. The node is submitted in toto cassette C1.

D. Part 4 received fresh for Tissue Banking, labeled with the patient's name, and "right upper lobe, is a 224 gram, 16.5 x 8.5 x 4.0 cm upper lobe of lung. This is also received fresh for frozen section diagnosis. The surgeon changed his mind. The pleura is pink/tan and spongy to red with anthracotic marbling. The lung is sectioned to have a 1.5 x 1.5 x 1.0 cm tumor mass. The mass appears circumscribed and possibly within a vessel. The mass is 2.0 cm from the bronchial margin and does not involve the pleura. The tumor appears to have an adjacent smaller nodule, which ranges up to 0.5 cm. The lung is sectioned fresh to have a peripheral pink/tan spongy appearance on the anterior surface in the superior aspect. The tumor has a central location adjacent to the hilar structures. There is focal scant mucin filled bronchioles in the area of the tumor. The parenchyma demonstrates mild congestion inferiorly. No additional masses or lesions are identified. Sections are sampled as labeled in the following cassettes:

- D1 - frozen section residue of bronchial margin
- D2 - hilar lymph nodes
- D3 - vascular margins

** CONTINUED ON NEXT PAGE **

[page 3 of 4]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED] Specimen Inquiry
PCI User: [REDACTED] Lab Database:

PAGE 3

SPEC #: [REDACTED] PATIENT: [REDACTED] (Continued)

GROSS DESCRIPTION: (Continued)

- D4 - perpendicular section of bronchus from margin towards tumor
- D5-D7 - representative sections of tumor to include separate small nodule of tumor
- D8 - parenchyma from superior aspect of lobe
- D9 - parenchyma adjacent to tumor from mid aspect of lobe
- D10 - inferior sections of parenchyma sampled

The specimen is dissected in an unfixed state for Tumor Banking. Received a call from the Operating Room just before [REDACTED] stating that [REDACTED] wanted a bronchial resection margin frozen. The Tumor Banker brought the specimen over but at that time, [REDACTED] did not want the bronchial resection margin frozen.

E. Part 5 is received in formalin, labeled with the patient's name and "level 10" are two hemorrhagic to focally blackened anthracotic portions of possible lymphoid tissue. The tissues include a 0.4 cm fragment and a 0.6 cm fragment. The tissues are submitted in toto cassette E1.

INTRAOPERATIVE CONSULTATION:

- A. FROZEN SECTION AND CYTOLOGY SMEARS, LEVEL 7 LYMPH NODE, BIOPSY:
- REACTIVE LYMPH NODE
- B. FROZEN SECTION, LEVEL 4 LEFT LYMPH NODE, BIOPSY:
- REACTIVE LYMPH NODE
- D. FROZEN SECTION, RIGHT UPPER LOBE:
- BRONCHIAL RESECTION MARGIN NEGATIVE FOR MALIGNANCY
- SPECIMEN DISSECTED FOR TUMOR BANKING

PHOTO DOCUMENTATION

** CONTINUED ON NEXT PAGE **

[page 4 of 4]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

Specimen Inquiry
Lab Database:

PAGE 4

SPEC #: [REDACTED]

PATIENT: [REDACTED]

(Continued)

PHOTO DOCUMENTATION

(Continued)

Signed ____ (signature on file) ____ [REDACTED]

** END OF REPORT **

Source: NCI Genomic Data Commons file 670f0342-6ceb-4eb3-9c78-6b787cd333d2 (TCGA-L9-A444.7356DDFB-ADA7-4809-85EC-1C6D51D5B32D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).